MMRF case MMRF_1539 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b7bea28f-ba89-44a1-a082-97d3755d5dfe

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.5 years (20,993 days); ISS stage: II; Days to last known disease status: 1,242 days (3.4 years); Days to last follow up: 1,242 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 45 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 227 days; Days to treatment end: 227 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 230 days; Days to treatment end: 230 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 327 days; Days to treatment end: 1,181 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 605 days (1.7 years); Days to treatment end: 878 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 878 days (2.4 years); Days to treatment end: 1,181 days (3.2 years).
   Treatment given: Therapeutic agents: Daratumumab + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,181 days (3.2 years); Days to treatment end: 1,361 days (3.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 473 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 6.74 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 4.46 µg/mL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 25.8 ×10⁹/L; Absolute Neutrophil 16.5 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 7.21 mmol/L; C-Reactive Protein 1.94 mg/dL.
- Day 73 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 2.88 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.36 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 7.97 ×10⁹/L; Platelets 609 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 29 g/L; Total Protein 5.4 g/dL; Glucose 6.82 mmol/L.
- Day 157: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 4.2 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 18.4 ×10⁹/L; Absolute Neutrophil 15.5 ×10⁹/L; Platelets 433 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6 mmol/L.
- Day 256 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 4.79 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 4.97 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 7.65 mmol/L.
- Day 325 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.11 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.88 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 5.61 mmol/L.
- Day 402 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 3.59 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.
- Day 493 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 0.34 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 3.56 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 598 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 689 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 4.14 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 780 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.14 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 6 mmol/L.
- Day 878: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 4.9 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.57 µg/mL; Lactate Dehydrogenase 6.05 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.93 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.57 mmol/L.
- Day 984: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 4.87 µg/mL; Lactate Dehydrogenase 7.67 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.8 ×10⁹/L; Platelets 394 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 3.96 mmol/L.
- Day 1,054: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 4.01 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.43 µg/mL; Lactate Dehydrogenase 7.7 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.6 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 1,165 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.57 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.97 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.
- Day 1,242 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 113 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 4.01 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.03 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7.05 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -9: Weight: 55 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1539_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1539_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
- Sample MMRF_1539_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 325 days.
